Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5273, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5273-01A (Primary Tumor).

[page 1 of 2]
1 Final Diagnosis:

Brain, right frontal lobe, excisional biopsy: Grade 3 (of 4) fibrillary and gemistocytic astrocytoma (WHO, grade III). (See comment.)

TCGA - DB - 5273

Diagnosis Comment:

Section from posterior margin shows involvement by a moderate tumor infiltrate.

ADDENDA:

1p and 19q FISH studies were performed on cells within paraffin sections from tumor. Two hybridizations were performed: one with a 19q probe/control 19p pair and one with a 1p probe/control 1q pair. The 19q and 1p probes mapped to the regions that are commonly deleted in gliomas. The 19q to 19p probe ratio was 1.01. The 1p to 1q probe ratio was 0.99. For both probes, the normal ratio is approximately 1. Any ratio less than 0.80 is consistent with deletion of the chromosomal region of interest.

There was no evidence of 1p or 19q. However, approximately 45% of the cells had 3-4 copies of the 1p, 1, 19p and 19q probes. Similar results have been observed in other glioma specimens with gain of chromosomes 1 and 19. The results may also be consistent with tumor tetraploidy or aneuploidy.

[page 2 of 2]
This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration, and is to be used as an adjunct to existing clinical and pathological information. This test does not rule out other chromosome anomalies.

[REDACTED]

[REDACTED]

Preliminary Frozen Section Consultation:

High grade glioma forming a mass roughly 4.4 cm in greatest dimension. The right frontal posterior margin caudate is negative for tumor.

[REDACTED]

Gross Description:

Tissue from the brain (right frontal--8.1 x 6.0 x 3.1 cm; right frontal posterior margin caudate--2.4 x 1.9 x 0.8 cm)

Block Summary:

Part A: RT.FRONTAL TUMOR

- 1 RT FRONTAL TX
- 2 RT FRONTAL TX
- 3 RT FRONTAL TX
- 4 RT FRONTAL TX
- 5 RT FRONTAL TX
- 6 RT FRONTAL TX
- 7 RT FRONTAL TX
- 8 RT FRONTAL TX
- 9 RT FRONTAL TX
- 10 RT FRONTAL TX
- 11 RT FRONTAL TX
- 12 RT FRONTAL TX

Part B: RT FRONTAL TX POST MGN CAUDATE

- 1 RT FRONT TX PST MGN CAUDATE
- [REDACTED]

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 10cd3403-b36d-4fe8-8f0d-e1d1491fc753 (TCGA-DB-5273.A415E3DD-3B4F-4E69-B1C8-474D38E98A83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).